MMRF case MMRF_1365 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/57744ea1-673b-422a-bb9c-f06aed93b3b5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.2 years (23,822 days); ISS stage: II; Days to last known disease status: 375 days (1.0 years); Days to last follow up: 375 days (1.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 30 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 20 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 30 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 30 days; Days to treatment end: 30 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 60 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 67 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 375.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 171 mg/dL; Beta 2 Microglobulin 3.68 µg/mL; Lactate Dehydrogenase 6.82 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 12.4 ×10⁹/L; Absolute Neutrophil 8.3 ×10⁹/L; Platelets 338 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.1 mmol/L; Albumin 31 g/L; Total Protein 5.2 g/dL; Glucose 9.68 mmol/L; C-Reactive Protein 8.61 mg/dL.
- Day 77 (ECOG 2): Hemoglobin 5.15 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 373 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L.
- Day 183 (ECOG 0): M Protein 0 g/dL; Hemoglobin 5.64 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 294 ×10⁹/L.
- Day 250 (ECOG 0): Hemoglobin 6.2 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.15 mmol/L; Albumin 31 g/L; Total Protein 5.7 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day 0: Weight: 58 kg; Height: 162 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1365_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1365_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
